Surgical pathology report (de-identified scan), TCGA case TCGA-EY-A5W2, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site University of North Carolina, specimen TCGA-EY-A5W2-01A (Primary Tumor).

[page 1 of 5]
SURGICAL PATHOLOGY

Case Number :

Diagnosis:

A: Uterus with cervix, bilateral ovaries and fallopian tubes,
hysterectomy with bilateral salpingo-oophorectomies:

Histologic type: Endometrioid adenocarcinoma

Histologic grade: FIGO grade 3 (architectural grade 2, nuclear
grade 3)

Tumor site: Primary endometrial cancer

*ICD-O-3
Adenocarcinoma, endometrioid
8880/3*

Myometrial invasion: Outer half

*Site: Endometrium
C54.1*

Depth: 11 mm Wall thickness: 21 mm Percent: 52%

JW 3/18/13

Serosal involvement: Not identified

Lower uterine segment involvement: Present

Cervical involvement: Not identified

Adnexal involvement: Not identified

Other involved sites: Not identified

Cervical/vaginal margin and distance: Negative, widely free

Lymphovascular space invasion: Not identified

Regional lymph nodes (see other specimens B, C, D, E)

Total number involved: 0

Total number examined: 23

Additional pathologic findings:

- Leiomyomas with hyalinization and dystrophic calcifications
- Benign endocervical polyp

AJCC Pathologic Stage: pT1b pN0

FIGO (2009 classification) Stage Grouping: IB, grade 3

Note: This pathologic stage assessment is based on information
available at the time of this report, and is subject to change
pending clinical review and additional information.

[page 2 of 5]
B: Lymph nodes, right pelvic, regional lymph node dissection
- No tumor identified in 8 lymph nodes (0/8)

C: Lymph nodes, left pelvic, regional lymph node dissection
- No tumor identified in 8 lymph nodes (0/8)

D: Lymph nodes, right para-aortic, dissection
- No tumor identified in 4 lymph nodes (0/4)

E: Lymph nodes, left para-aortic, dissection
- No tumor identified in 3 lymph nodes (0/3)

Clinical History:

-year-old female with Grade 3 endometrioid adenocarcinoma on biopsy.

Gross Description:

Received are five appropriately labeled containers.

Container A:

Adnexa: present and attached

Weight: 235 grams

Shape: pear-shaped

Dimensions:

height: 12.2 cm

anterior to posterior width: 5.4 cm

breadth at fundus: 7.5 cm

Serosa: smooth, pink/tan, and glistening

Cervix:

ectocervix: white/pink, firm, and smooth

endocervix: tan/red and trabeculated, with a 0.7 x 0.5 x 0.5 mm

endocervical polyp noted on the anterior side, and cystic

distention of the posterior endocervix

length of endocervical canal: 2.7 cm

Endomyometrium:

length of endometrial cavity: 7.0 cm

width of endometrial cavity at fundus: 6.5 cm

tumor findings:

dimensions: 12.5 cm along the anterior wall, extending over the fundus and down the posterior by 6.5 cm wide x 3.0 cm in depth

[page 3 of 5]
appearance: white/tan, soft, polypoid, and fungating; there are areas of hemorrhage within the mass
location and extent: The mass involves the anterior, fundal, and posterior walls of the endometrium. It fills and distends the endometrial cavity. A few areas of endometrium appeared spared, especially the posterior lower uterine segment.
myometrial invasion: The tumor appears to invade into the inner one-half of the myometrium.

thickness of myometrial wall at deepest gross invasion: 1.2 cm
other findings or comments: Multiple intramural nodules ranging from 0.3 x 0.3 x 0.2 cm to 1.8 x 1.5 x 1.2 cm are noted. All are rubbery, white, and whorled.

Adnexa:

Right ovary:

dimensions: 2.2 x 1.2 x 1.0 cm

external surface: white and cerebriform

cut surface: unremarkable

Right fallopian tube:

dimensions: 4.5 x 0.5 cm

other findings: The lumen appears patent.

Left ovary:

dimensions: 2.1 x 1.0 x 0.9 cm

external surface: white and cerebriform

cut surface: has a 0.5 x 0.5 x 0.3 cm yellow, firm area with a serpiginous border, but is otherwise unremarkable

Left fallopian tube:

dimensions: 5.0 x 0.6 cm

other findings: The lumen appears patent.

Lymph nodes: please see parts B-E

Other comments: none

Digital photograph taken: not taken

Tissue submitted for special investigations: none

Block Summary:

- A1 - right ovary
- A2 - right fallopian tube
- A3 - right fimbria
- A4 - left ovary
- A5 - left fallopian tube
- A6 - left fimbria

[page 4 of 5]
A7 - anterior cervix with polyp
A8 - posterior cervix
A9 - anterior lower uterine segment
A10 - posterior lower uterine segment
A11 - anterior mid corpus, full thickness section
A12 - anterior fundus, full thickness section
A13 - posterior fundus, full thickness section
A14 - posterior corpus, full thickness section
A15-A16 - additional sections of posterior corpus at areas of grossly deepest invasion
A17 - additional sections of friable tumor mass
A18 - representative sections of white whorled nodules

Container B is additionally labeled "right pelvic nodes." It contains a 5.0 x 4.5 x 1.5 cm aggregate of yellow/pink fatty tissue. It contains six candidate lymph nodes ranging in size from 0.4 x 0.3 x 0.3 cm to 3.5 x 1.5 x 1.0 cm.

Block summary:

B1,B2 - first lymph node, serially sectioned
B3,B4 - second largest lymph node, serially sectioned
B5,B6 - each contains one lymph node, serially sectioned
B7 - multiple small lymph node candidates
B8-B10 - additional sections of fat, entirely submitted

Container C is additionally labeled "left pelvic nodes." It contains a 5.5 x 4.0 x 2.0 cm aggregate of pink/yellow fatty tissue. Seven lymph node candidates are palpated within the fat, measuring from 1.1 x 0.8 x 0.5 cm to 4.5 x 2.3 x 1.0 cm.

Block Summary:

C1-C3 - largest lymph node candidate, entirely submitted
C4-C9 - each contains one lymph node candidate, serially sectioned
C10-C11 additional sections of fat, entirely submitted

Container D is additionally labeled "right periaortic." It contains a 5.0 x 1.0 x 0.8 cm strip of yellow/brown fatty, cauterized tissue. Three candidate lymph nodes are palpated within the tissue measuring 0.5 x 0.5 x 0.3 cm, 0.7 x 0.5 x 0.4 cm, and 1.3 x 0.9 x 0.6 cm.

[page 5 of 5]
Block Summary:

- D1 - largest lymph node, serially sectioned
- D2 - two smaller candidate lymph nodes
- D3 - remainder of tissue, entirely submitted

Container E is additionally labeled "left periaortic." It contains two pieces of tissue. The first is a candidate lymph node measuring 1.6 x 1.1 x 0.8 cm, with a small amount of attached fatty tissue. The second is a 0.5 x 0.5 x 0.4 cm candidate lymph node attached to a 2.0 x 1.2 x 0.4 cm piece of yellow/brown fatty tissue. The larger lymph node candidate and attached fat are serially sectioned and submitted entirely in blocks E1 and E2. The smaller lymph node candidate is bisected and submitted with the entirety of the remainder of the tissue in block E3.

Source: NCI Genomic Data Commons file 6f3f5b12-6074-4260-a321-345d164d968a (TCGA-EY-A5W2.C09EED3C-50CC-47CB-BA81-96D05E53D9F0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).